Somatic mutation profile of tumor specimen TCGA-NJ-A7XG-01A (aliquot TCGA-NJ-A7XG-01A-12D-A397-08) from TCGA case TCGA-NJ-A7XG, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.6 years (18,127 days).
Specimen TCGA-NJ-A7XG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df21a677-bf91-4f94-be05-7be5f87730fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A7XG-10A (Blood Derived Normal), aliquot TCGA-NJ-A7XG-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99503d51-c6d3-4116-9952-485963a90730

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 18, Silent 14, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14609C>A p.A4870D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391979139, COSV101291214, COSV68949468; called by muse, mutect2, varscan2
- ASH1L | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs766289374, COSV100853191; called by muse, mutect2, varscan2
- CELSR3 | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.276); catalogued as COSV99372806; called by muse, mutect2, varscan2
- COL4A1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128683, COSV65422174; called by muse, mutect2, varscan2
- GNPDA2 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV99776811; called by muse, mutect2, varscan2
- HMGB2 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99632630; called by muse, mutect2
- HSPA8 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV99914257; called by muse, mutect2
- MYO16 | c.2624A>T p.E875V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99193622; called by muse, mutect2, varscan2
- OR13C5 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs1318716563, COSV101053029, COSV101053130; called by muse, mutect2, varscan2
- ORC2 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs16835624; called by muse, mutect2, varscan2
- OSBPL11 | c.2054T>A p.L685Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954016; called by muse, mutect2, varscan2
- RBM15 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.481); catalogued as COSV100873406; called by muse, mutect2, varscan2
- RTP4 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.267); catalogued as COSV99372243; called by muse, mutect2, varscan2
- SLIT2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs192894188, COSV56562325; called by muse, mutect2, varscan2
- SLITRK2 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100157417; called by muse, mutect2, varscan2
- TANC1 | c.2439C>G p.C813W | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV99713241; called by muse, mutect2, varscan2
- TUBB2A | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100373789; called by muse, mutect2, varscan2
- TUBGCP3 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs768319104, COSV56187773, COSV56191579; called by muse, mutect2, varscan2
- ZAN | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV100769336, COSV61813109; called by muse, mutect2, varscan2
- CATSPERG | c.1223_1224del p.E408Vfs*5 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- DHDH | c.859dup p.Y287Lfs*2 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- HYDIN | c.10097del p.N3366Tfs*33 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel, varscan2
- NUFIP1 | c.1319del p.N440Tfs*20 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- ABCC1 | c.528C>T p.Y176= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as rs200973377, COSV100578844; called by muse, mutect2, varscan2
- AURKC | c.183G>T p.R61= (on ENST00000302804 / NM_001015878.2; = p.R27= on NM_003160.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100248774; called by muse, mutect2, varscan2
- CCM2 | c.690C>T p.D230= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99347577; called by muse, mutect2
- CCSER1 | c.1089A>C p.S363= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100388611; called by muse, mutect2, varscan2
- CEP72 | c.1437G>A p.L479= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99374551; called by muse, mutect2, varscan2
- FLG | c.5769C>T p.D1923= | Silent (SNP) | VAF 90/307 reads (29%) | catalogued as COSV100910842; called by muse, mutect2, varscan2
- IGFN1 | c.3216G>A p.P1072= (on ENST00000295591 / NM_001367841.1; = p.P3529= on NM_001164586.2) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs761660706, COSV99811392; called by muse, mutect2, varscan2
- MDH1B | c.1545C>A p.T515= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs202190889, COSV100982146; called by muse, mutect2, varscan2
- PAPOLB | c.645G>A p.V215= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV101271291; called by muse, mutect2, varscan2
- RBFOX1 | c.1056C>T p.Y352= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs372365163; called by muse, mutect2, varscan2
- RPH3AL | c.405G>A p.L135= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100046581; called by muse, mutect2
- SYNE1 | c.23655A>T p.V7885= (on ENST00000367255 / NM_182961.4; = p.V7814= on NM_033071.3) | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99555781; called by muse, mutect2, varscan2
- UMODL1 | c.1158C>T p.D386= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs376462517; called by muse, mutect2, varscan2
- ZNF330 | c.129C>T p.D43= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99522434; called by muse, mutect2
